Surgical pathology report (de-identified scan), TCGA case TCGA-NC-A5HL, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Washington University - CHUV, specimen TCGA-NC-A5HL-01A (Primary Tumor).

ICD 6-3
Carcinoma, squamous cell ^{NDS}
8070/3
Site: ^B Lung, upper lobe
C34.1
9/2/11/13

Synoptic translated report

Site : Right lung superior lobe

☒ Central ☐ Peripheral ☐ NA

Number of lesion :

1. Lung squamous cell carcinoma

Tumor size:

1. 5.5 cm (diameter)

Visceral pleural invasion: ☐ Yes ☒ No ☐ NA

Chest wall invasion : ☐ Yes ☒ No ☐ NA

Histological diagnosis : Poorly differentiated squamous cell carcinoma with peripheral squamous cell carcinoma in situ

Node status : N1(2/26) (intrapulmonary lymph nodes)

TNM : T2b N1 (2/26) G3 R0

Pathologist signature:

Date:

Source: NCI Genomic Data Commons file 5a79981a-8a32-437d-82d2-43729cd4ba59 (TCGA-NC-A5HL.1B861502-417D-4B21-980A-DD2749660DD5.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).